Somatic mutation profile of tumor specimen TCGA-09-2044-01B (aliquot TCGA-09-2044-01B-01D-0704-01) from TCGA case TCGA-09-2044, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.3 years (28,231 days).
Specimen TCGA-09-2044-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6220e5c-4580-4cb3-a02f-adb157cb8890.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-2044-10A (Blood Derived Normal), aliquot TCGA-09-2044-10A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81a1cd70-343e-49b1-aba6-44a7886bb74d

The open-access MAF lists 78 somatic variants for this specimen: 62 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 15, Frame Shift Del 7, Nonsense Mutation 2, Splice Site 2, In Frame Del 2, Splice Region 2, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.10156A>T p.T3386S | Missense Mutation (SNP) | VAF 56/71 reads (79%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV101316086; called by muse, mutect2, varscan2
- ARMC8 | c.817_819del p.D273del (on ENST00000469044 / NM_001363941.2; = p.D259del on NM_014154.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 24/160 reads (15%) | catalogued as rs1255356910; called by pindel, varscan2
- ASPH | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65245971; called by muse, mutect2, varscan2
- B4GALT5 | c.338C>A p.T113N | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV65494546; called by muse, mutect2, varscan2
- BDKRB1 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV53706722; called by muse, mutect2, varscan2
- BPIFB2 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99401445; called by muse, varscan2
- BPTF | c.3136G>C p.V1046L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV58842430; called by muse, varscan2
- C9orf72 | c.1372G>C p.G458R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66163734, COSV66163764; called by muse, mutect2, varscan2
- CCDC62 | c.1126T>G p.C376G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV99457255; called by muse, mutect2, varscan2
- CGA | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.093); catalogued as COSV63644744; called by muse, mutect2
- COL7A1 | c.7052G>C p.G2351A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60398879; called by mutect2, varscan2
- CTNNB1 | c.1955-2A>G p.X652_splice | Splice Site (SNP) | VAF 20/101 reads (20%) | catalogued as COSV62703256; called by muse, mutect2, varscan2
- CYP2C19 | c.1097T>A p.L366Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV64908617; called by muse, varscan2
- CYP7B1 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV59593278; called by muse, mutect2, varscan2
- DDIAS | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61272759; called by muse, mutect2, varscan2
- DSN1 | c.354A>C p.T118= | Splice Region (SNP) | VAF 38/113 reads (34%) | catalogued as COSV65519160, COSV65519754; called by muse, mutect2, varscan2
- EIF4A1 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV51511545; called by muse, varscan2
- FAM199X | c.1093T>C p.F365L | Missense Mutation (SNP) | VAF 47/61 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV55434139; called by muse, mutect2, varscan2
- FAT3 | c.2609T>G p.V870G | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV53146082; called by muse, mutect2, varscan2
- FCHSD1 | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.214); catalogued as COSV71301513; called by muse, varscan2
- FRMPD3 | c.2218G>A p.V740M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99346437; called by muse, varscan2
- GLRA3 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV56866317, COSV56871195; called by muse, mutect2, varscan2
- GPATCH2L | c.1062A>T p.K354N | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.139); catalogued as COSV55050024; called by mutect2, varscan2
- H2AC20 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as COSV58612664; called by muse, mutect2
- HCN1 | c.1183G>T p.A395S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV100300612, COSV57508510; called by mutect2, varscan2
- IFI35 | c.511G>T p.V171F (on ENST00000415816 / NM_001330230.2; = p.V173F on NM_005533.5) | Missense Mutation (SNP) | VAF 97/114 reads (85%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55896687; called by muse, mutect2, varscan2
- IL18RAP | c.712G>T p.V238F | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757197083, COSV51827677; called by muse, mutect2, varscan2
- IL31RA | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV61695599; called by muse, mutect2, varscan2
- ITGA4 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99276419; called by muse, mutect2, varscan2
- KCNT2 | c.2844T>G p.C948W | Missense Mutation (SNP) | VAF 54/74 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54080058, COSV54094303; called by muse, mutect2, varscan2
- LILRA1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as rs748102322, COSV52179133, COSV52182929; called by muse, mutect2, varscan2
- LIPK | c.1009A>G p.I337V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1319963721, COSV68201538; called by muse, mutect2
- MET | c.662A>G p.E221G | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.999); catalogued as COSV59265312; called by muse, mutect2, varscan2
- MOCS1 | c.1085A>G p.K362R | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV51368064; called by muse, mutect2, varscan2
- MYO10 | c.5228C>T p.A1743V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV57025957; called by mutect2, varscan2
- MYO1B | c.2292G>C p.W764C | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV58434890; called by muse, mutect2, varscan2
- NPPA | c.451T>C p.Y151H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV56741834; called by muse, mutect2, varscan2
- PAXBP1 | c.2158T>G p.S720A | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.101); catalogued as COSV51610796; called by muse, mutect2
- RASAL2 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV62718499; called by muse, mutect2, varscan2
- RMI2 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 162/314 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56964289; called by muse, varscan2
- RYR2 | c.2189T>C p.L730P | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63699659; called by muse, mutect2, varscan2
- SLC26A8 | c.2446C>T p.R816W | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs754358341, COSV100839487; called by mutect2, varscan2
- SLCO6A1 | c.180G>T p.R60S | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV65806812; called by muse, varscan2
- TDP1 | c.1187_1193del p.G396Vfs*24 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as COSV59644625; called by mutect2, pindel, varscan2
- TEAD3 | c.90T>G p.D30E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as COSV58817651; called by muse, mutect2, varscan2
- TGM2 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100821654; called by muse, mutect2, varscan2
- TKTL2 | c.1340G>T p.C447F | Missense Mutation (SNP) | VAF 59/66 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54919865, COSV54920168; called by muse, mutect2, varscan2
- TMEM45A | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as rs765084110, COSV100058282; called by muse, varscan2
- UBQLNL | c.1361A>C p.E454A | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV100974532; called by muse, mutect2, varscan2
- UGT1A10 | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60845661; called by muse, varscan2
- VPS16 | c.2216A>G p.D739G | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.446); catalogued as COSV66791823, COSV66797027; called by muse, mutect2, varscan2
- ATG2A | c.5817_*26del | Nonstop Mutation (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- ATG2B | c.2737-4_2737-3dup | Splice Region (INS) | VAF 24/68 reads (35%) | called by mutect2, pindel
- GXYLT1 | c.714_715delinsT p.T239Hfs*15 | Frame Shift Del (DEL) | VAF 20/85 reads (24%) | called by pindel, varscan2*
- INPP4B | c.733_735del p.D245del | In Frame Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel*
- KANK1 | c.3898-3_3898-2del p.X1300_splice | Splice Site (DEL) | VAF 3/23 reads (13%) | called by mutect2, pindel
- MCRS1 | c.636del p.E213Rfs*5 | Frame Shift Del (DEL) | VAF 3/17 reads (18%) | called by mutect2, pindel*
- PNP | c.90_91del p.I30Mfs*10 | Frame Shift Del (DEL) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.2411_2420del p.D804Afs*5 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- TSC1 | c.2162_2172del p.R721Qfs*9 | Frame Shift Del (DEL) | VAF 20/28 reads (71%) | called by mutect2, pindel
- VN1R5 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 109/202 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- YLPM1 | c.3248_3251del p.L1083* | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | called by pindel, varscan2
- ABCF3 | c.1599C>G p.T533= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV53053694; called by muse, mutect2, varscan2
- ACAT1 | c.783T>C p.F261= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as COSV54921674; called by muse, varscan2
- CD109 | c.3340A>C p.R1114= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV54653401, COSV99754807; called by muse, varscan2
- EEFSEC | c.903G>T p.G301= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV54629198; called by muse, mutect2
- ERCC4 | c.2340C>T p.S780= | Silent (SNP) | VAF 28/248 reads (11%) | catalogued as COSV61313101; called by muse, mutect2
- FAT4 | c.4359T>A p.G1453= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV67893923; called by muse, mutect2, varscan2
- FGF14 | c.523T>C p.L175= | Silent (SNP) | VAF 33/44 reads (75%) | catalogued as COSV65950768; called by muse, varscan2
- KIF3C | c.1335C>A p.P445= | Silent (SNP) | VAF 48/59 reads (81%) | catalogued as COSV53100798; called by muse, mutect2, varscan2
- MEI1 | c.825G>C p.G275= | Silent (SNP) | VAF 2/22 reads (9%) | called by muse, mutect2
- PHF20 | c.2079C>A p.T693= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as COSV100926591; called by mutect2, varscan2
- PPEF2 | c.9C>T p.S3= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs367898608, COSV54422289; called by muse, mutect2, varscan2
- PRRT2 | c.138G>A p.E46= | Silent (SNP) | VAF 9/10 reads (90%) | catalogued as rs1291344054, COSV54885200; called by muse, mutect2, varscan2
- SMAP2 | c.271C>A p.R91= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs754479305, COSV101019084, COSV65531591; called by mutect2, varscan2
- SSRP1 | c.1494C>T p.N498= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs768189674, COSV53480510; called by mutect2, varscan2
- SURF6 | c.429G>A p.E143= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV64395681; called by muse, mutect2
- MTRNR2L6 | chr7:142671120 A>G | 3'Flank (SNP) | VAF 31/74 reads (42%) | called by muse, mutect2, varscan2
